Gene-level copy-number profile of tumor specimen TCGA-AN-A03Y-01A from TCGA case TCGA-AN-A03Y, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 66.3 years (24,232 days).
Specimen TCGA-AN-A03Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.da97f597-b09e-40b2-8517-e98c3e643ce3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AN-A03Y-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fa13e24a-7005-44bc-8bbb-605e80a5c8d4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 11; copy number 2: 15,611; copy number 3: 18,124; copy number 4: 18,641; copy number 5: 2,985; copy number 7: 1,019; copy number 10: 6; copy number 11: 1,584; copy number 12: 87; copy number 14: 1,470; copy number 15: 22; copy number 16: 42; copy number 25: 50; copy number 34: 79; copy number 39: 45; copy number 41: 1; copy number 53: 36.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AN-A03Y-01A-21D-A011-01): tumor purity 0.67, ploidy 3.6, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,422 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:168,400,829–168,495,685, 1 gene, copy number 10 (within-gene range 7–10): AL023755.1.
- chr1:168,449,672–168,582,069, 5 genes, copy number 10: QRSL1P1, XCL2, AL031736.1, XCL1, AL031736.2.
- chr1:170,115,636–248,919,946, 1,584 genes, copy number 11 (broad region; genes not listed).
- chr8:41,577,187–47,738,164, 104 genes, copy number 12–41 (broad region; genes not listed).
- chr8:49,330,210–145,066,685, 1,470 genes, copy number 14 (broad region; genes not listed).
- chr11:68,870,664–70,436,584, 51 genes, copy number 15–39: LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,706,068, 6 genes, copy number 12: AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1.
- chr11:72,285,495–72,434,680, 1 gene, copy number 12 (within-gene range 2–16): CLPB.
- chr11:72,354,516–78,574,874, 200 genes, copy number 12–53 (within-gene range 2–53) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
